Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LJ-01A (Primary Tumor).

[page 1 of 2]
1ED-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries
- 2: SP: Right distal IP ligament
- 3: SP: Left external iliac lymph nodes
- 4: SP: Left internal iliac lymph nodes
- 5: SP: Left obturator lymph nodes
- 6: SP: Right external iliac lymph nodes
- 7: SP: Right obturator lymph nodes
- 8: SP: Right internal iliac lymph nodes
- 9: SP: Right para-aortic lymph nodes
- 10: SP: Right common iliac lymph nodes
- 11: SP: Left common iliac lymph nodes
- 12: SP: Left para-aortic lymph nodes

adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1 w
5/1/11

DIAGNOSIS:

- 1) UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES; HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE I (<= 6% SOLID GROWTH), NUCLEAR GRADE 2.
- NO DEFINITIVE MYOMETRIAL INVASION IDENTIFIED.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: COMPLEX HYPERPLASIA WITH ATYPIA.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITIES: ADENOMYOSIS AND ADENOMYOMATOUS POLYP.
- ALL ADNEXAE ARE UNREMARKABLE.
- BENIGN PARATUBAL CYSTS AT RIGHT SIDE.
- 2) IP LIGAMENT, RIGHT DISTAL; BIOPSY:
- BENIGN FIBROVASCULAR AND ADIPOSE TISSUE.
- 3) LYMPH NODES, LEFT EXTERNAL ILIAC; BIOPSY:
- THREE BENIGN LYMPH NODES (0/3).

** Continued on next page **

aw 5/1/11

[page 2 of 2]
- 4) LYMPH NODE, LEFT INTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODE, LEFT OBTURATOR; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC; BIOPSY:
- SEVEN BENIGN LYMPH NODES (0/7).
- 7) LYMPH NODES, RIGHT OBTURATOR; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 8) LYMPH NODES, RIGHT INTERNAL ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 9) LYMPH NODES, RIGHT PARA-AORTIC; BIOPSY:
- FOUR BENIGN LYMPH NODES (0/4).
- 10) LYMPH NODE, RIGHT COMMON ILIAC; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPH NODE IDENTIFIED.
- 11) LYMPH NODE, LEFT COMMON ILIAC; BIOPSY:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPH NODE IDENTIFIED.
- 12) LYMPH NODES, LEFT PARA-AORTIC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 8c694460-1f00-4eec-a0b8-f292f4e7b213 (TCGA-AP-A0LJ.859CBF70-D72E-4843-B3AA-6226B707AA2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).